Somatic mutation profile of tumor specimen TCGA-77-7338-01A (aliquot TCGA-77-7338-01A-11D-2042-08) from TCGA case TCGA-77-7338, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.3 years (23,480 days).
Specimen TCGA-77-7338-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 859785f3-b354-4ee5-a1d3-026d51894bf5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-7338-11A (Solid Tissue Normal), aliquot TCGA-77-7338-11A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c008d43-d30d-44d4-a188-fe2704243249

The open-access MAF lists 143 somatic variants for this specimen: 98 protein-altering or splice-affecting, 43 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 43, Nonsense Mutation 4, Splice Site 4, Frame Shift Del 4, Frame Shift Ins 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 25/67 reads (37%) | catalogued as rs1554656411, CM063892, COSV58688166; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 24/74 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1555526131, COSV52674926, COSV52693942, COSV52759722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- A1CF | c.682T>C p.S228P | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as COSV99256930; called by muse, mutect2
- ADAM22 | c.1010G>T p.S337I | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); catalogued as COSV99717515; called by muse, mutect2, varscan2
- ADAMTS12 | c.2242C>G p.P748A | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100711326; called by muse, mutect2, varscan2
- AFF1 | c.1821dup p.P608Tfs*61 | Frame Shift Ins (INS) | VAF 12/55 reads (22%) | catalogued as rs1560640290; called by mutect2, pindel, varscan2
- AHNAK2 | c.3364G>T p.V1122L | Missense Mutation (SNP) | VAF 94/238 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV100318208; called by muse, mutect2, varscan2
- AKAP13 | c.4555G>C p.E1519Q | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100774101, COSV63363181; called by muse, mutect2, varscan2
- AL645922.1 | c.1217G>C p.G406A | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV100191263, COSV54962176; called by muse, mutect2, varscan2
- AMOTL1 | c.436C>G p.Q146E | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV100133856; called by muse, mutect2
- ARHGEF26 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs1331408967, COSV100726641; called by muse, mutect2, varscan2
- ATP13A4 | c.808G>T p.A270S | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs1196272635, COSV55066276, COSV55076321; called by muse, mutect2
- ATP1A2 | c.1367A>T p.K456M | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100767972; called by muse, mutect2, varscan2
- BRINP3 | c.1783G>T p.D595Y | Missense Mutation (SNP) | VAF 51/289 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV100819087, COSV66540830; called by muse, mutect2, varscan2
- C12orf40 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs867271556, COSV100210380; called by muse, mutect2, varscan2
- CCDC54 | c.918C>G p.I306M | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); catalogued as rs1192151519, COSV53759231, COSV99660260; called by muse, mutect2, varscan2
- CD163 | c.3259G>A p.G1087R | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.089); catalogued as COSV100775981; called by muse, mutect2, varscan2
- CEP112 | c.2145C>G p.F715L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV101210903; called by muse, mutect2
- CFHR2 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66381604; called by muse, mutect2, varscan2
- CNDP2 | c.159G>C p.K53N | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100159195; called by muse, mutect2, varscan2
- COL12A1 | c.2548C>G p.P850A | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100486227; called by muse, mutect2, varscan2
- CPZ | c.1164C>A p.Y388* (on ENST00000360986 / NM_001014447.3; = p.Y377* on NM_003652.3) | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100249066; called by muse, mutect2, varscan2
- CRTAP | c.424T>A p.F142I | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs1212795586, COSV100310143; called by muse, mutect2, varscan2
- CTNNA2 | c.962C>G p.S321C | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100785104; called by muse, mutect2, varscan2
- CUBN | c.9376A>G p.N3126D | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as rs750933671, COSV100913061; called by muse, mutect2, varscan2
- CYP11B1 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV52831449; called by muse, mutect2, varscan2
- DCP1B | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV99767665; called by muse, mutect2, varscan2
- DNAH7 | c.4661A>G p.D1554G | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100416094; called by muse, mutect2, varscan2
- DST | c.7478A>G p.E2493G | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV99758009; called by muse, mutect2, varscan2
- ELMO1 | c.2135C>G p.P712R | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100165094, COSV60302869; called by muse, mutect2, varscan2
- EPB41L3 | c.2447C>A p.T816N | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as COSV100549681; called by muse, mutect2, varscan2
- F11R | c.892C>A p.L298M | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99231150; called by muse, mutect2, varscan2
- FAM167A | c.234del p.Q79Rfs*7 | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | catalogued as COSV52702654, COSV52703303; called by mutect2, pindel, varscan2
- FMN2 | c.3365C>G p.P1122R | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as COSV100144675, COSV100146133; called by muse, mutect2, varscan2
- FOXF1 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1481006723, CM132156, COSV99296619; called by muse, mutect2
- GFRA1 | c.641G>T p.C214F | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100815531, COSV100815848; called by muse, mutect2, varscan2
- GRID2 | c.359A>T p.Q120L | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99943259; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs193204072, COSV100736447; called by muse, mutect2, varscan2
- H2BC18 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.25); catalogued as COSV100516139; called by muse, mutect2, varscan2
- HADHA | c.1474G>C p.E492Q | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.517); catalogued as COSV101024042; called by muse, mutect2
- IFT140 | c.1382G>C p.G461A | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs764203704, COSV101276510; called by muse, mutect2, varscan2
- KEAP1 | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV50418315, COSV99408002; called by muse, mutect2, varscan2
- KIF6 | c.509+1G>C p.X170_splice | Splice Site (SNP) | VAF 9/58 reads (16%) | catalogued as rs762834670, COSV54674268, COSV99759604; called by muse, mutect2, varscan2
- KRTAP10-11 | c.505T>C p.C169R | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV100554486; called by muse, mutect2, varscan2
- LOXL1 | c.1405G>T p.G469C | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99985385; called by muse, mutect2
- MAGEL2 | c.2308C>A p.P770T | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.578); catalogued as COSV100046055; called by muse, mutect2, varscan2
- MEAK7 | c.1331G>T p.R444L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV100640420, COSV100640432; called by muse, mutect2, varscan2
- MYH13 | c.414G>C p.E138D | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV99354609; called by muse, mutect2, varscan2
- MYH7 | c.895+1G>A p.X299_splice | Splice Site (SNP) | VAF 14/112 reads (13%) | catalogued as rs111547156, COSV62517456; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOM1 | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99867454; called by muse, mutect2, varscan2
- NACA2 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV71713155; called by muse, mutect2
- NKAIN4 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 73/277 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53900801, COSV99416874; called by muse, mutect2, varscan2
- OR10Q1 | c.158T>G p.V53G | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100372346; called by muse, mutect2
- OR1S2 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100224274; called by muse, mutect2, varscan2
- OR2T11 | c.779A>T p.Q260L | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV100424878; called by muse, mutect2, varscan2
- OR5AP2 | c.386A>G p.Y129C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100266309; called by muse, mutect2, varscan2
- OR5B17 | c.740T>A p.F247Y | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV100641929; called by muse, mutect2, varscan2
- OR5B3 | c.431T>C p.I144T | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.02); catalogued as COSV100512028; called by muse, mutect2, varscan2
- PAX6 | c.1123C>A p.P375T | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV99570627; called by muse, mutect2, varscan2
- PCDHGA5 | c.2288C>A p.S763* | Nonsense Mutation (SNP) | VAF 49/165 reads (30%) | catalogued as COSV53907148, COSV99541943; called by muse, mutect2, varscan2
- PDE4DIP | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.104); catalogued as COSV100520306, COSV57720372; called by muse, mutect2, varscan2
- PLEC | c.6206C>T p.A2069V (on ENST00000322810 / NM_201380.4; = p.A1959V on NM_000445.5) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.106); catalogued as rs201624086, COSV100512609; called by muse, mutect2
- PLG | c.76G>A p.V26M | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV99804882; called by muse, mutect2, varscan2
- PLPPR4 | c.940A>G p.I314V | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as rs760141215, COSV100926850; called by muse, mutect2, varscan2
- PLSCR2 | c.710C>G p.S237C (on ENST00000497985 / NM_001199978.1; = p.S164C on NM_020359.2) | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100367786; called by muse, mutect2, varscan2
- PLXNA4 | c.3182G>T p.W1061L | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV100325474, COSV58116250; called by muse, mutect2, varscan2
- PNISR | c.956A>C p.E319A | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV100984388; called by muse, mutect2, varscan2
- PRICKLE1 | c.980C>G p.S327* | Nonsense Mutation (SNP) | VAF 36/148 reads (24%) | catalogued as COSV100566530; called by muse, mutect2, varscan2
- RAB6C | c.476C>G p.A159G | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); catalogued as COSV101308532, COSV69339881; called by muse, mutect2, varscan2
- RCBTB2 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs1566306050, COSV100749604; called by muse, mutect2
- RFC1 | c.1693G>T p.G565C | Missense Mutation (SNP) | VAF 53/228 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as rs768993651, COSV100567840; called by muse, mutect2, varscan2
- RIN1 | c.796C>G p.P266A | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100254786, COSV60926239; called by muse, mutect2
- SALL1 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.895); catalogued as COSV51756280, COSV51756293; called by muse, mutect2, varscan2
- SALL1 | c.231T>A p.N77K | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV99175055; called by muse, mutect2, varscan2
- SLC35F1 | c.637+2T>C p.X213_splice | Splice Site (SNP) | VAF 27/180 reads (15%) | catalogued as COSV100837821; called by muse, mutect2, varscan2
- SLC8A2 | c.1907C>T p.T636I | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.176); catalogued as COSV99370154; called by muse, mutect2, varscan2
- SMARCAD1 | c.1093G>C p.D365H | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs1386342255, COSV100758979; called by muse, mutect2
- SPICE1 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs141190252, COSV55620351, COSV55624417; called by muse, mutect2, varscan2
- SPTLC2 | c.772A>T p.S258C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99377702; called by muse, mutect2, varscan2
- SSH2 | c.2627G>T p.R876L | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52167560, COSV99282494; called by muse, mutect2, varscan2
- TCN2 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as COSV53191763; called by muse, mutect2
- TMEM260 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99840235, COSV99840495; called by muse, mutect2, varscan2
- TP63 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53203752, COSV99287706; called by muse, mutect2, varscan2
- TSGA13 | c.793C>A p.Q265K | Missense Mutation (SNP) | VAF 53/255 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.582); catalogued as COSV100449685, COSV58406688; called by muse, mutect2, varscan2
- TTBK2 | c.2180G>A p.R727K | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV99142065; called by muse, mutect2
- TTPA | c.230G>A p.R77K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99478561; called by muse, mutect2
- UBAC1 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.484); catalogued as rs145619460; called by muse, mutect2, varscan2
- VGLL1 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV101034667; called by muse, mutect2, varscan2
- ZNF106 | c.2438G>A p.G813D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55513286, COSV99782836; called by muse, mutect2, varscan2
- ZNF385B | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100416170; called by muse, mutect2, varscan2
- ZNF440 | c.1726G>C p.V576L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.981); catalogued as COSV100407630; called by mutect2, varscan2
- ZNF449 | c.1379A>G p.E460G | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as COSV100203021; called by muse, mutect2, varscan2
- ZNF98 | c.52G>C p.V18L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100757537; called by muse, mutect2, varscan2
- CDK8 | c.900_901del p.H300Qfs*3 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- EFR3A | c.324_325del p.E109Ifs*21 | Frame Shift Del (DEL) | VAF 3/20 reads (15%) | called by mutect2, pindel*
- IGLV3-16 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- MRC1 | c.3650-1G>T p.X1217_splice | Splice Site (SNP) | VAF 49/304 reads (16%) | called by muse, mutect2, varscan2
- PLCG1 | c.1206del p.F402Lfs*78 | Frame Shift Del (DEL) | VAF 31/101 reads (31%) | called by mutect2, pindel, varscan2
- ADGRB3 | c.2289C>T p.G763= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs761752486, COSV65388679, COSV65393176; called by muse, mutect2, varscan2
- BOLA1 | c.87C>T p.I29= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV64967732; called by muse, mutect2, varscan2
- CACNA1C | c.987C>T p.G329= | Silent (SNP) | VAF 37/177 reads (21%) | catalogued as COSV100220076; called by muse, mutect2, varscan2
- CACNG8 | c.489G>C p.G163= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99555067, COSV99555070; called by muse, mutect2, varscan2
- CDH7 | c.630C>T p.V210= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV59898468; called by muse, mutect2, varscan2
- COL1A2 | c.2634G>A p.S878= | Silent (SNP) | VAF 12/176 reads (7%) | catalogued as rs762339011, COSV51964121, COSV99798460; ClinVar: likely benign; called by muse, mutect2
- COL25A1 | c.759T>A p.I253= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV101211528; called by muse, mutect2, varscan2
- CYP11B1 | c.75C>A p.G25= | Silent (SNP) | VAF 52/144 reads (36%) | catalogued as rs760261276, COSV52827702, COSV99455359; called by mutect2, varscan2
- DGKI | c.2589G>C p.A863= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV99935784; called by muse, mutect2, varscan2
- DNAH5 | c.8730G>T p.L2910= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV99451571; called by muse, mutect2, varscan2
- DSEL | c.2481G>A p.L827= | Silent (SNP) | VAF 29/136 reads (21%) | catalogued as COSV100025863; called by muse, mutect2, varscan2
- ECEL1 | c.12G>T p.P4= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100458831; called by muse, mutect2, varscan2
- F5 | c.1566A>G p.L522= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs1458802858, COSV100889173; called by muse, mutect2, varscan2
- FASN | c.2220G>T p.V740= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100148045; called by muse, mutect2, varscan2
- FZD2 | c.1536G>A p.P512= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs1383642373, COSV59530182; called by muse, mutect2, varscan2
- GBA | c.156G>C p.S52= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100516399, COSV100516407; called by muse, mutect2, varscan2
- GGTLC2 | c.447G>A p.E149= | Silent (SNP) | VAF 6/168 reads (4%) | called by muse, mutect2
- GPC5 | c.135C>A p.V45= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100994725; called by muse, mutect2, varscan2
- GRIN2B | c.4047T>C p.F1349= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV101663112; called by muse, mutect2, varscan2
- HTR1A | c.1200C>T p.Y400= | Silent (SNP) | VAF 51/224 reads (23%) | catalogued as COSV60500110; called by muse, mutect2, varscan2
- IRX1 | c.636C>A p.G212= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs772666856, COSV100116628, COSV57362693; called by muse, mutect2, varscan2
- ITGB2 | c.193C>A p.R65= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV100185984; called by muse, varscan2
- KDM3B | c.3816G>A p.K1272= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV100069918; called by muse, mutect2, varscan2
- KIRREL2 | c.702G>A p.S234= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs771624645, COSV52880058; called by muse, mutect2, varscan2
- LGR5 | c.336C>T p.G112= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs764850360, COSV99878129; called by muse, mutect2, varscan2
- LIFR | c.2835G>C p.V945= | Silent (SNP) | VAF 61/188 reads (32%) | catalogued as COSV99664764; called by muse, mutect2, varscan2
- MARCHF10 | c.2169T>C p.G723= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100248349; called by muse, mutect2, varscan2
- MRPL20 | c.330A>G p.P110= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as rs372508725; called by muse, mutect2, varscan2
- NOS1 | c.3675T>A p.A1225= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV100500935; called by muse, mutect2, varscan2
- PARD3B | c.957G>A p.P319= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs750163275, COSV62510315; called by muse, mutect2, varscan2
- PEAK1 | c.903G>C p.L301= | Silent (SNP) | VAF 5/96 reads (5%) | catalogued as COSV100433229; called by muse, mutect2
- PLCXD1 | c.948C>G p.L316= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs780227650, COSV100397712, COSV58205306; called by muse, mutect2, varscan2
- POM121L12 | c.696G>A p.R232= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV101374830, COSV101374943; called by muse, mutect2, varscan2
- PSD | c.1290C>T p.A430= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV99192984; called by muse, mutect2, varscan2
- SC5D | c.798C>G p.L266= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV99873139; called by muse, mutect2, varscan2
- SCN4A | c.2610G>A p.A870= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs375918619, COSV71125416; called by muse, mutect2, varscan2
- SLC25A40 | c.63C>T p.A21= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs759249636, COSV100353763; called by muse, mutect2, varscan2
- SPAG4 | c.1243T>C p.L415= | Silent (SNP) | VAF 37/121 reads (31%) | catalogued as COSV100958318; called by muse, mutect2, varscan2
- SS18L1 | c.240G>A p.T80= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs765950209, COSV100065096, COSV59213030; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2724A>G p.P908= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs754498231, COSV100562016; called by muse, mutect2, varscan2
- TMEM132A | c.348A>G p.Q116= | Silent (SNP) | VAF 28/207 reads (14%) | catalogued as COSV99136084; called by muse, mutect2, varscan2
- TTC26 | c.1470G>T p.L490= | Silent (SNP) | VAF 35/135 reads (26%) | catalogued as COSV100571081; called by muse, mutect2, varscan2
- ZNF106 | c.552T>C p.G184= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as COSV99782837; called by muse, mutect2, varscan2
- KRT18P23 | chr22:44570577 C>T | 3'Flank (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- MIR329-2 | n.44G>A | RNA (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
